Somatic mutation profile of tumor specimen TARGET-10-PARVCG-09A (aliquot TARGET-10-PARVCG-09A-01D) from TARGET case TARGET-10-PARVCG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,659 days).
Specimen TARGET-10-PARVCG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ad015df-7843-40ca-8993-5d1df8a46a68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARVCG-10A (Blood Derived Normal), aliquot TARGET-10-PARVCG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45f036a3-ba38-4ccc-ad1d-b8a56ce27fad

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CENPE | c.4394T>A p.I1465K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV54392303; called by muse, mutect2, varscan2
- KCNJ4 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1288306473; called by muse, mutect2, varscan2
- MGAT4C | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs566418071, COSV59832100, COSV59837748; called by muse, mutect2, varscan2
- NRBP1 | c.1556A>G p.N519S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs768298741; called by muse, mutect2, varscan2
- POC5 | c.1624A>T p.T542S (on ENST00000428202 / NM_001099271.2; = p.T517S on NM_152408.2) | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs1207070560; called by muse, mutect2, varscan2
- POSTN | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.679); catalogued as COSV65715030; called by muse, mutect2, varscan2
- RABL6 | c.1222A>G p.T408A | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs374393527; called by muse, mutect2, varscan2
- APOB | c.7062C>G p.I2354M | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- GALNTL5 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GEMIN2 | c.229A>C p.K77Q | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- IGKV3D-20 | chr2:90039479 TCCCACAGTGATTC>G | Missense Mutation (DEL) | VAF 12/42 reads (29%) | called by pindel, varscan2*
- PRORP | c.931_933delinsGCCTATCAGGA p.N311Afs*16 | Frame Shift Ins (INS) | VAF 18/46 reads (39%) | called by pindel, varscan2*
- DCX | c.27C>T p.D9= | Silent (SNP) | VAF 21/23 reads (91%) | catalogued as COSV57576341; called by muse, mutect2, varscan2
- STK36 | c.3516C>A p.A1172= | Silent (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- ZDHHC14 | c.246-13424G>A | Intron (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
